Somatic mutation profile of tumor specimen TCGA-CQ-6224-01A (aliquot TCGA-CQ-6224-01A-11D-1912-08) from TCGA case TCGA-CQ-6224, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 52.2 years (19,051 days).
Specimen TCGA-CQ-6224-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e367168b-d2c4-4958-a97a-64668281f5c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-6224-10A (Blood Derived Normal), aliquot TCGA-CQ-6224-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/162127a5-94fe-4532-9f69-e898f2d3b08c

The open-access MAF lists 63 somatic variants for this specimen: 41 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 19, Nonsense Mutation 3, RNA 1, Intron 1, Frame Shift Del 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 16/87 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.13327G>A p.A4443T | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV101315423; called by muse, mutect2, varscan2
- ATP8A2 | c.2431C>T p.R811W | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as rs560280973, COSV54937988, COSV54969698; called by muse, mutect2, varscan2
- ATRX | c.3202A>G p.T1068A | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV100969943; called by muse, mutect2, varscan2
- CCDC85A | c.857G>T p.C286F | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.063); catalogued as COSV101339358; called by muse, mutect2, varscan2
- CCNA1 | c.343C>G p.P115A | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV99714257; called by muse, mutect2
- DBX1 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.9); catalogued as rs763778118, COSV57054453; called by mutect2, varscan2
- DCAF15 | c.1524C>T p.L508= | Splice Region (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99585748; called by muse, mutect2, varscan2
- DEGS1 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV100083276; called by muse, mutect2, varscan2
- DMBT1 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 42/483 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV100351948; called by muse, mutect2
- ELOA2 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs202180726, COSV55305117; called by muse, mutect2
- EPDR1 | c.302G>C p.G101A | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.185); catalogued as COSV52258355, COSV52259557; called by muse, mutect2
- EXOC6 | c.2365G>A p.V789I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.085); catalogued as COSV99591367; called by muse, mutect2, varscan2
- GAB2 | c.235G>C p.E79Q (on ENST00000361507 / NM_080491.3; = p.E41Q on NM_012296.3) | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs748627150, COSV100416205; called by muse, mutect2, varscan2
- GALNT16 | c.181A>T p.T61S | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV100545692; called by muse, mutect2
- HMCN1 | c.13534C>T p.R4512* | Nonsense Mutation (SNP) | VAF 30/107 reads (28%) | catalogued as rs766364489, COSV54929103; called by muse, mutect2, varscan2
- ICAM5 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.877); catalogued as rs1235315412, COSV99703072; called by muse, mutect2, varscan2
- INTS12 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100415651; called by muse, mutect2, varscan2
- KAAG1 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.634); catalogued as rs1192251469, COSV99219666; called by muse, mutect2, varscan2
- KLF9 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 15/89 reads (17%) | catalogued as COSV65807579; called by muse, mutect2, varscan2
- KMT2C | c.1409G>A p.C470Y | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1319381877, COSV100065922; called by muse, mutect2, varscan2
- KRTAP5-2 | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV101295067, COSV69014941; called by muse, mutect2
- LRP4 | c.4492C>T p.R1498W | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1431817175, COSV66135820, COSV66138108; called by muse, mutect2
- OGT | c.1256C>T p.T419M | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as COSV65483032; called by muse, mutect2
- OPRK1 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.412); catalogued as rs200385989; called by muse, mutect2
- PKHD1 | c.5707G>A p.V1903I | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs753639079, COSV61884120, COSV61891662; called by muse, mutect2, varscan2
- PTPDC1 | c.1942G>A p.E648K (on ENST00000375360 / NM_177995.3; = p.E700K on NM_152422.4) | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99997309; called by muse, mutect2, varscan2
- PYROXD2 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs367654216; called by muse, mutect2, varscan2
- RASA1 | c.2366G>A p.R789Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57196517, COSV57198182, COSV99169866; called by muse, mutect2, varscan2
- SAR1A | c.29A>G p.N10S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs200845256; called by mutect2, varscan2
- SPAG16 | c.1406G>A p.R469K | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as rs746602409, COSV100529792; called by muse, mutect2, varscan2
- STAB2 | c.3428G>C p.R1143P | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101185592; called by muse, mutect2, varscan2
- SYNJ2BP | c.296G>A p.R99K | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs755190221, COSV56445843, COSV99832577; called by muse, mutect2, varscan2
- TC2N | c.1022A>T p.D341V | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV100562709; called by muse, mutect2, varscan2
- TNS2 | c.272C>A p.T91K (on ENST00000314250 / NM_170754.4; = p.T101K on NM_015319.2) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV100047361, COSV58576699; called by muse, mutect2, varscan2
- TOP2B | c.4819G>A p.V1607I (on ENST00000264331 / NM_001330700.2; = p.V1602I on NM_001068.3) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.03); catalogued as rs764317223, COSV99979048; called by muse, mutect2, varscan2
- TTN | c.72898G>A p.V24300I (on ENST00000591111; = p.V16876I on NM_003319.4) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | PolyPhen possibly damaging (0.64); catalogued as rs928158833, COSV100592518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.21385G>T p.A7129S (on ENST00000591111; = p.A6202S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/85 reads (16%) | PolyPhen benign (0); catalogued as COSV100592520, COSV100619238; called by muse, mutect2, varscan2
- TNS2 | c.515del p.K172Sfs*14 (on ENST00000314250 / NM_170754.4; = p.K182Sfs*14 on NM_015319.2) | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel, varscan2
- ZFPM1 | c.2921G>C p.R974P | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABLIM3 | c.633G>A p.E211= | Silent (SNP) | VAF 47/174 reads (27%) | catalogued as rs201700201, COSV100448020; called by muse, mutect2, varscan2
- ADGRE5 | c.2223G>A p.T741= (on ENST00000242786 / NM_078481.4; = p.T648= on NM_001784.5) | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs141170739; called by muse, mutect2, varscan2
- EXTL3 | c.222C>T p.C74= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs376405458; called by muse, mutect2, varscan2
- GDF5 | c.648G>A p.V216= | Silent (SNP) | VAF 41/209 reads (20%) | catalogued as rs747277301, COSV100976711; called by muse, mutect2, varscan2
- IRX5 | c.399C>T p.N133= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as rs1185354785, COSV100315605, COSV58058507; called by muse, mutect2, varscan2
- KCNH4 | c.1284G>A p.A428= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs550145042, COSV99236701; called by muse, mutect2, varscan2
- LHFPL3 | c.501T>C p.L167= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV67811857; called by muse, mutect2, varscan2
- LRRN3 | c.1455C>T p.G485= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs760533901, COSV57822603; called by mutect2, varscan2
- MRPL21 | c.582G>A p.R194= | Silent (SNP) | VAF 15/296 reads (5%) | catalogued as COSV100751871; called by muse, mutect2
- NEUROD1 | c.978C>T p.C326= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as rs184871420; called by muse, mutect2
- OR4D1 | c.441C>T p.A147= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs372813872; called by muse, mutect2, varscan2
- PCYT2 | c.303C>T p.T101= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as rs764987799, COSV100155392; called by muse, mutect2, varscan2
- PSD2 | c.1119G>A p.P373= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs200076969, COSV51199985; called by muse, mutect2
- SLC52A2 | c.1035G>A p.L345= | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as COSV100095444; called by muse, mutect2, varscan2
- SLC7A14 | c.1263G>A p.L421= | Silent (SNP) | VAF 14/119 reads (12%) | catalogued as COSV99200320; called by muse, mutect2, varscan2
- ST14 | c.2022C>T p.A674= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV99598455; called by muse, mutect2, varscan2
- TYRO3 | c.2151G>C p.A717= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV55482452; called by mutect2, varscan2
- UGT1A1 | c.192C>T p.A64= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV100529416; called by muse, mutect2, varscan2
- USP9X | c.6384G>A p.L2128= | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as COSV100198400; called by muse, mutect2, varscan2
- CHD4 | c.4643-107C>G | Intron (SNP) | VAF 6/80 reads (8%) | catalogued as COSV100537245; called by muse, mutect2
- TFE3 | c.*291C>T | 3'UTR (SNP) | VAF 26/61 reads (43%) | catalogued as COSV100252282; called by muse, mutect2, varscan2
- TMEM183B | n.931A>G | RNA (SNP) | VAF 93/370 reads (25%) | catalogued as rs1412636636; called by muse, mutect2, varscan2
